Surgical pathology report (de-identified scan), TCGA case TCGA-77-8150, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8150-01A (Primary Tumor).

[page 1 of 3]
Collected [REDACTED]

Histopathology Report

SEE SUPPLEMENTARY REPORT BELOW [REDACTED]

HISTORY

Frozen section. Squamous cell carcinoma. Trunchus intermedius.

MACROSCOPIC

Six specimens received:

1: The specimen is unlabelled and consists of a fragment of tissue measuring 6 x 4 x 3 mm. [BIT, 1A].

FROZEN SECTION DIAGNOSIS:

No evidence of malignancy.

Phoned to [REDACTED]

2: The specimen is labelled '(R) lung' and consists of a right lung measuring 220 mm superior to inferior, 160 mm anterior to posterior and 90 mm medial to lateral. The upper and lower lobes are formed well. The right middle lobe is quite rudimentary and the horizontal fissure is only very poorly formed. The pleural surface is quite ragged particularly over the right lower lobe. A piece of redundant pleura is present at the inferolateral aspect of this lobe. Several discrete areas of firm induration can be palpated over the medial surface of the right lower lobe. The pleural surface of the right upper lobe is much smoother, however the lung itself is quite firm in the inferior aspect of the right upper lobe and a firm mass can be palpated in the right lower lobe close to the hilar region. On sectioning of the lung the right upper lobe is largely free of pathology. In the right lower lobe numerous perihilar lymph nodes can be seen and a firm tumour mass measuring 43 x 25 x 20 mm. It has an endobronchial component approaching to within 7 mm of the bronchial resection margin and appearing to completely obstruct the right lower lobe bronchus. The right lower lobe is nearly completely replaced by pneumonia and large amounts of tenacious pus are noted throughout this lobe of lung. [2A-B, bronchial resection margin, 2A is the upper lobe bronchus, 2B is the lower lobe bronchus; 2C-H, peribronchial lymph nodes; 2I, endobronchial tumour; 2J-L, tumour close to resection margin; 2M, lower lobe lung including pneumonia; 2N, bullous area of lung from the upper lobe; 2O, normal lung and subpleural lymph node from the upper lobe; 2P, area of attached redundant pleura from the lower lobe].

3: The specimen is labelled 'No. 3 lymph node' and consists of a piece of nodal tissue measuring 15 x 19 x 10 mm. [Bisected and BIT, 3A].

4: The specimen is labelled 'No. 7 plus 8 lymph node' and consists of nodal tissue measuring 35 x 15 x 20 mm. [Sectioned and BIT, 4A-C].

5: The specimen is labelled 'No. 9 lymph node and consists of a piece of nodal

[page 2 of 3]
Histopathology Report

tissue measuring 20 x 15 x 10 mm. [Bisected and BIT, 5A].

6: The specimen is labelled 'No. 10 lymph node' and consists of a piece of nodal tissue measuring 15 x 10 x 10 mm. [Bisected and BIT, 6A].

MICROSCOPIC

1: Paraffin sections confirm the frozen section diagnosis of no evidence of malignancy. The biopsy includes bronchial cartilage and seromucinous glands and surrounding fibroadipose tissue.

2: Sections show a moderately differentiated squamous cell carcinoma that is forming a polypoid endobronchial mass and is invading through the bronchial wall and into the adjacent lung and hilar fibroadipose tissue. Pleural invasion is not identified. There is no blood vessel invasion and no lymphatic permeation is seen. Perineural permeation is identified and this extends closely to (0.3 mm) a hilar soft tissue margin. The lesion is well clear of the bronchial resection margin. At the bronchial resection, squamous metaplasia is identified. There is involvement of peribronchial lymph nodes within the region of the tumour. Distal to the tumour, there is evidence of obstructive pneumonitis with mild bronchiectasis. The uninvolved lung shows mild respiratory bronchiolitis, peribronchial dust deposition and emphysema. Elastic pulmonary arteries show mild atheroma. The attached pleural adhesion appears fibrotic. Within the peribronchial lymph nodes, there are silicotic nodules together with prominent sinus histiocytosis. Focally the histiocytes are forming poorly developed granulomata. The granulomata may be in response to the tumour however, a rare granuloma contains central necrosis and special stains for micro-organisms will be undertaken. A large silicotic nodule is present in the subpleural lymph node.

3: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

4: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

5: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

6: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

SUMMARY

1-6: Right lung and lymph nodes:

A: Moderately differentiated squamous cell carcinoma; 43 mm in maximal dimension.

[page 3 of 3]
[REDACTED]

Collected [REDACTED]

— **Histopathology Report**

B: Perineural permeation identified but no blood vessel or lymphatic invasion present.

C: No pleural invasion identified; clear of bronchial margin but close to hilar soft tissue margin (0.3 mm).

D: Peribronchial lymph node metastases.

E: T3N1

F: Non-neoplastic lung: Emphysema and mild respiratory bronchiolitis.

[REDACTED]

SUPPLEMENTARY REPORT

1: No microorganisms are identified within the lymph node granulomata with special stains (Grocott and Ziehl-Neelsen).

[REDACTED]

SUPPLEMENTARY REPORT

2: A further section of the tumour has been examined [2Q]. The tumour appears confined to the bronchus in this sectioned and there is no involvement of the hilar margin. The section containing the close nerve is said to be in the region of the frozen section.

[REDACTED]

c.c. Lung Cancer Registry

—

Source: NCI Genomic Data Commons file 653154b0-3410-4050-a71a-f2d3d47d72da (TCGA-77-8150.D19C8493-374A-4B6A-9975-5F220C77834B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).